Surgical pathology report (de-identified scan), TCGA case TCGA-NH-A8F8, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Candler, specimen TCGA-NH-A8F8-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: ACCT # LOC
REG DR: AGE/SX: M ROOM:
DOB: BED:
STATUS: DIS:

SPEC #: RECD: STATUS: PERFORMED
COLL: TIME IN FORMALIN: hrs.
COLD ISCHEMIA TIME: mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Colon CA, R/O metastatic liver involvement

Remarks:

- Specimen(s): A. Wedge biopsy liver
B. Right hemicolectomy
C. Wedge biopsy liver #2

MICROSCOPIC DIAGNOSIS

- A. WEDGE BIOPSY LIVER #1:
- METASTATIC COLONIC ADENOCARCINOMA PRESENT ON PERMANENT SECTION BUT NOT SEEN ON FROZEN SECTION
- B. PORTION RIGHT COLON, PORTION TERMINAL ILEUM AND APPENDIX, RIGHT HEMICOLECTOMY:
- ADENOCARCINOMA OF ASCENDING COLON, LOW GRADE
- TUMOR MEASURES 5 CM AND PENETRATES VISCERAL PERITONEUM
- SURGICAL MARGINS FREE OF TUMOR WITH NEAREST MARGIN 8 CM FROM TUMOR, RADIAL AND PROXIMAL
- METASTATIC ADENOCARCINOMA PRESENT IN 15 OF 22 REGIONAL LYMPH NODES WITH EXTRACAPSULAR EXTENSION
- SEE COMMENT FOR SYNOPTIC REPORT
- C. WEDGE BIOPSY LIVER #2:
- METASTATIC COLONIC ADENOCARCINOMA

ICD O-3

Adenocarcinoma NOS S140/3
Site Cecum/ascending colon C18.2
JIS 4/2/14

COMMENT(S)

SURGICAL PATHOLOGY CANCER CASE SUMMARY - CAP APPROVED

Specimen: Terminal ileum, cecum, appendix, ascending colon
Procedure: Right hemicolectomy
Tumor Site: Right (ascending) colon
Tumor Size: 5 cm in greatest dimension
Macroscopic Tumor Perforation: Not identified
Histologic Type: Adenocarcinoma
Histologic Grade: Low-grade
Microscopic Tumor Extension: Tumor penetrates to the surface of the visceral peritoneum (serosa)
Margins: Distance of invasive carcinoma from closest margin: 8cm

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE
RUN TIME
RUN USER

PAGE 2

SPEC #:

PATIENT:

(Continued)

COMMENT(S)

(Continued)

Treatment Effect:	Specify Margin: Proximal and radial
Lymph-Vascular Invasion:	No prior treatment
Perineural Invasion:	Present
Tumor Deposits:	Not identified
Pathologic Staging:	Present
	Primary Tumor: pT4a
	Regional Lymph Nodes: pN2b
	Number examined: 22
	Number involved: 15
	Distant Metastasis: pM1; liver

GROSS DESCRIPTION:

The specimen is received in the fresh state from the operating room in three parts.

A. This is a piece of tan tissue measuring 10 x 10 x 2 mm, totally examined by frozen section as block A1.

B. This specimen, received in the fresh state from the operating room for immediate gross evaluation for evaluation of surgical margins and tumor banking is a right hemicolectomy specimen. The colon measures 24 cm in length by 6 cm in maximum diameter; the terminal ileum measures 6 cm in length by 2 cm in diameter; the appendix measures 7 x 0.8 cm. Present in the ascending colon is a circumferential, tan tumor which measures 5 x 5 x 5 cm located 8 cm from the radial margin, 8 cm from the proximal margin, and 12 cm from the distal margin. Tissue of the overlying visceral peritoneum is puckered suggestive of visceral peritoneal penetration. Blue ink is applied to these regions. Regional adipose tissue attached to the specimen measures 15 x 13 x 3 cm. A representative section of the tumor is submitted for tumor banking. Multiple regional lymph nodes are positive for metastatic tumor, the largest measuring 1.5 cm in greatest dimension and exhibiting extracapsular extension of the tumor. The following sections are submitted:

- B1 - appendix and proximal margin
- B2 - distal margin
- B3-6 - colon mass with blue ink on abnormal visceral peritoneum
- B7 - colon mass
- B8,9 - whole lymph nodes
- B10-12- representative sections of positive lymph nodes

C. This is a wedge biopsy of liver measuring 1 x 1 x 0.5 cm. Portions of the tissue appear to be replaced by tumor. A representative section is examined by frozen section as block C1. All remaining tissue is submitted as block C2.

INTRAOPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS WEDGE BIOPSY LIVER #1:
- FIBROSIS

B. IMMEDIATE GROSS EVALUATION RIGHT HEMICOLECTOMY:

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 3

SPEC #:

PATIENT: [REDACTED]

(Continued)

INTRAOPERATIVE CONSULTATION: (Continued)

- ADENOCARCINOMA
- SURGICAL MARGINS FREE OF TUMOR
- SPECIMEN PROCESSED FOR TUMOR BANKING

C. FROZEN SECTION DIAGNOSIS WEDGE BIOPSY LIVER #2:

- METASTATIC ADENOCARCINOMA

PHOTO DOCUMENTATION

Image . Picture Copy Error
Image . Picture Copy Error
Image . Picture Copy Error
Image . Picture Copy Error
Image . Picture Copy Error

Signed ____ (signature on file) [REDACTED]

** END OF REPORT **

Source: NCI Genomic Data Commons file 9e204191-2bfb-4acf-921b-6039fa590323 (TCGA-NH-A8F8.0D65923F-583D-42C2-8CA3-0A209D5F0490.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).